Surgical pathology report (de-identified scan), TCGA case TCGA-Y8-A898, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Spectrum Health, specimen TCGA-Y8-A898-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

Research Dx

Left partial nephrectomy:

Papillary renal cell carcinoma, type 1.

ICD O-3
Carcinoma, papillary renal
cell 826013
Site @ Kidney NOS C64.9
JW 11/22/13

CASE SUMMARY FOR NEPHRECTOMY FOR RENAL CELL CARCINOMA:

Procedure: Partial nephrectomy

Specimen laterality: Left

Tumor site: Upper pole (posterior)

Tumor size: 2.4 cm in greatest dimension

Extent of disease: Tumor limited to kidney

Histologic type: Papillary renal cell carcinoma, type 1

Sarcomatoid features: Not identified

Tumor necrosis: Not identified

Histologic grade (Fuhrman Nuclear Grade): Not applicable

Margins: Focally extends to the cauterized inked parenchymal resection margin of the specimen

Lymphovascular invasion: Not identified

Pathologic staging (pTNM):

Primary tumor: pT1a: Tumor 4 cm less in greatest dimension, limited to the kidney

Regional lymph nodes: pNX: Cannot be assessed

Pathologic findings in nonneoplastic kidney: Chronic inflammation, congestion and dystrophic calcifications.

Other tumors and/or tumor-like lesions: None identified

AJCC Staging (7th edition) pT1a pNX pM not applicable

Research QC

Tumor:

95% tumor nuclei

0% necrosis

5% normal

Normal:

na

Research Specimen

-

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

Buffy coat frozen time:

Warm ischemia start time

Cold ischemia start time:

Formalin fixation start time:

Total cold ischemia time

Formalin fixation stopped time:

Total formalin fixation time:

[page 2 of 2]
Specimen Weight

Tumor
1-69 mg, 2-102 mg

Specimen Size

Plasma x 3
Serum x 2
Buffy coat x 1

Cryovials x 2
Tumor x 2

FFPE x 2
Tumor x 2

Study

Patient Consent
Yes

Source: NCI Genomic Data Commons file 3bf22160-e9c7-4fa3-aefb-f3f1ac58b0fa (TCGA-Y8-A898.508CD8F7-03FB-4141-888D-7B00DAB8B206.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).